Somatic mutation profile of tumor specimen C3L-02802-02 (aliquot CPT0174890011) from CPTAC case C3L-02802, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G1; Age at diagnosis: 56.5 years (20,647 days).
Specimen C3L-02802-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dbb20bb5-4ea5-45ee-8a91-24e2a708e920.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02802-31 (Blood Derived Normal), aliquot CPT0175510002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b290334-05dd-4d1b-83a8-33912f47489c

The open-access MAF lists 89 somatic variants for this specimen: 63 protein-altering or splice-affecting, 20 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 20, Frame Shift Del 5, Intron 2, 3'UTR 2, Nonsense Mutation 1, In Frame Del 1, Frame Shift Ins 1, In Frame Ins 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 119/476 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- FGFR2 | c.1647T>A p.N549K | Missense Mutation (SNP) | VAF 172/365 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913476, COSV60638757, COSV60639738; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 134/318 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SOX17 | c.287C>G p.A96G | Missense Mutation (SNP) | VAF 22/353 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52023963; called by muse, mutect2
- ATP2B3 | c.835G>A p.V279I | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as rs781838590; called by muse, mutect2
- CCDC7 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs113888697; called by muse, mutect2, varscan2
- CDH4 | c.926C>T p.T309M | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs895024295, COSV100848575, COSV64661310; called by muse, mutect2, varscan2
- CUX1 | c.1274G>A p.R425H (on ENST00000437600 / NM_181500.4; = p.R427H on NM_001913.5) | Missense Mutation (SNP) | VAF 39/263 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs372464298; called by muse, mutect2, varscan2
- DNAH12 | c.8983G>A p.G2995R (on ENST00000351747; = p.G3863R on NM_001366028.2) | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs114075870; called by muse, mutect2, varscan2
- DOC2B | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 64/272 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1480171369; called by muse, mutect2, varscan2
- EML4 | c.551C>A p.S184Y | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as COSV100580978; called by muse, mutect2, varscan2
- FAT3 | c.8662A>T p.T2888S | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53076152; called by muse, mutect2, varscan2
- GABRA4 | c.898A>C p.T300P | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51922305; called by muse, mutect2, varscan2
- GRM3 | c.1322C>T p.T441M | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); catalogued as rs1372002096; called by muse, mutect2
- IQCN | c.3310G>T p.A1104S | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as rs1468422669; called by muse, mutect2, varscan2
- LCE2A | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 67/289 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.059); catalogued as rs371432619; called by muse, mutect2, varscan2
- LRG1 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.719); catalogued as rs1431003592, COSV56702391; called by muse, mutect2, varscan2
- MAP2K5 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1277129284, COSV99460161; called by muse, mutect2, varscan2
- ME2 | c.436A>G p.I146V | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.025); catalogued as rs1264970506; called by muse, mutect2, varscan2
- MROH1 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs764106973, COSV58192894; called by muse, mutect2
- MYO1G | c.2269C>T p.R757W | Missense Mutation (SNP) | VAF 125/581 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs558918192; called by muse, mutect2, varscan2
- NBPF14 | c.3709G>A p.V1237M | Missense Mutation (SNP) | VAF 18/456 reads (4%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.791); catalogued as rs1280458721; called by muse, mutect2
- OR1S2 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs112423118, COSV100224333; called by muse, mutect2, varscan2
- OR4P4 | c.931C>A p.L311I | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV58920860; called by muse, mutect2, varscan2
- PICALM | c.1559C>G p.S520C | Missense Mutation (SNP) | VAF 47/301 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs900306092; called by muse, mutect2, varscan2
- PIEZO2 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 49/273 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.938); catalogued as rs1035950451, COSV100123684; called by muse, mutect2, varscan2
- PRKD3 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 58/201 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745406511; called by muse, mutect2, varscan2
- RBM47 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 81/516 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55931980; called by muse, mutect2, varscan2
- RGS21 | c.282C>A p.D94E | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748082665; called by muse, mutect2, varscan2
- SLC26A11 | c.267C>G p.F89L | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.39); catalogued as COSV58338981; called by muse, mutect2, varscan2
- SLC35C1 | c.997G>A p.G333S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as rs757642463; called by muse, mutect2
- SNX18 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750201994; called by muse, mutect2, varscan2
- TBC1D9 | c.3619C>T p.R1207W | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.586); catalogued as rs754331118, COSV71307494; called by muse, mutect2, varscan2
- TENT5C | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs766689047, COSV65616542; called by muse, mutect2, varscan2
- TNC | c.5026G>A p.D1676N | Missense Mutation (SNP) | VAF 17/404 reads (4%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.646); catalogued as COSV100406448; called by muse, mutect2
- TPO | c.1259C>T p.A420V | Missense Mutation (SNP) | VAF 94/358 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.71); catalogued as rs1294060096; called by muse, mutect2, varscan2
- TRUB1 | c.812A>G p.N271S | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs149298330, COSV53929779; called by muse, mutect2
- ARAP3 | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 51/244 reads (21%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ARHGAP32 | c.2600C>T p.T867I (on ENST00000310343 / NM_001378025.1; = p.T518I on NM_014715.4) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- CCND1 | c.866_868dup p.D289dup | In Frame Ins (INS) | VAF 18/73 reads (25%) | called by pindel, varscan2
- CHD6 | c.1602G>T p.M534I | Missense Mutation (SNP) | VAF 18/518 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.241); called by muse, mutect2
- CIC | c.1817_1818del p.V606Gfs*83 | Frame Shift Del (DEL) | VAF 20/136 reads (15%) | called by pindel, varscan2
- COG1 | c.2334_2335del p.Q779Sfs*6 | Frame Shift Del (DEL) | VAF 71/377 reads (19%) | called by mutect2, pindel, varscan2
- CYLC2 | c.645del p.D216Ifs*17 | Frame Shift Del (DEL) | VAF 20/131 reads (15%) | called by mutect2, pindel, varscan2
- DYM | c.1154A>T p.H385L | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- FREM3 | c.2923A>G p.K975E | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT tolerated (0.82); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- FUS | c.158G>A p.S53N | Missense Mutation (SNP) | VAF 70/266 reads (26%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- H2AC17 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 64/354 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ID1 | c.166C>G p.L56V | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- MED13L | c.5972C>T p.A1991V | Missense Mutation (SNP) | VAF 82/360 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- MTMR11 | c.161G>A p.W54* | Nonsense Mutation (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- MYH14 | c.675_693+1del | Frame Shift Del (DEL) | VAF 26/210 reads (12%) | called by mutect2, pindel
- NFE2L2 | c.101_103del p.R34_E35delinsQ | In Frame Del (DEL) | VAF 20/164 reads (12%) | called by mutect2, pindel
- PSG6 | c.601C>G p.L201V | Missense Mutation (SNP) | VAF 66/389 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTGDR | c.499C>A p.P167T | Missense Mutation (SNP) | VAF 49/293 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SKOR2 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 56/209 reads (27%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- SLC7A13 | c.769A>C p.N257H | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOX17 | c.403dup p.Y135Lfs*27 | Frame Shift Ins (INS) | VAF 31/174 reads (18%) | called by mutect2, pindel, varscan2
- TLL1 | c.891G>C p.M297I | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- TRPV1 | c.2507C>T p.S836F | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); called by mutect2, varscan2
- TXNDC11 | c.2866_2872del p.A956Pfs*58 (on ENST00000356957 / NM_001303447.2; = p.A929Pfs*58 on NM_015914.7 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 29/173 reads (17%) | called by mutect2, pindel, varscan2
- WNK3 | c.1892A>T p.Q631L | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF79 | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 45/293 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- ADGRA1 | c.210C>T p.F70= | Silent (SNP) | VAF 43/175 reads (25%) | catalogued as rs751421975, COSV66925130; called by muse, mutect2, varscan2
- CHAC1 | c.661C>T p.L221= | Silent (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- DISP3 | c.3478C>T p.L1160= | Silent (SNP) | VAF 76/158 reads (48%) | catalogued as rs987426114; called by muse, mutect2, varscan2
- EZHIP | c.996C>T p.A332= | Silent (SNP) | VAF 88/398 reads (22%) | catalogued as rs782433378, COSV57956724; called by muse, mutect2, varscan2
- FSCB | c.1467C>T p.A489= | Silent (SNP) | VAF 43/152 reads (28%) | catalogued as rs748894618, COSV61217195; called by muse, mutect2, varscan2
- MPZ | c.78G>A p.P26= | Silent (SNP) | VAF 39/197 reads (20%) | catalogued as rs777790314; called by muse, mutect2, varscan2
- PCDH17 | c.558C>T p.R186= | Silent (SNP) | VAF 50/320 reads (16%) | catalogued as COSV100931489; called by muse, mutect2, varscan2
- PCDHA7 | c.771C>T p.I257= | Silent (SNP) | VAF 22/281 reads (8%) | called by muse, mutect2
- PCDHB9 | c.1506C>T p.S502= | Silent (SNP) | VAF 92/588 reads (16%) | catalogued as COSV53378758; called by muse, mutect2, varscan2
- PCDHGB6 | c.1617G>A p.S539= | Silent (SNP) | VAF 78/379 reads (21%) | catalogued as rs781534809, COSV53912228; called by muse, mutect2, varscan2
- RP1L1 | c.5496C>T p.A1832= | Silent (SNP) | VAF 12/217 reads (6%) | catalogued as rs369137346; called by muse, mutect2
- S100PBP | c.1119C>T p.Y373= | Silent (SNP) | VAF 29/130 reads (22%) | catalogued as rs919565834; called by muse, mutect2, varscan2
- SPTBN4 | c.1263G>A p.L421= | Silent (SNP) | VAF 51/256 reads (20%) | called by muse, mutect2, varscan2
- SPTY2D1 | c.21C>T p.L7= | Silent (SNP) | VAF 32/188 reads (17%) | catalogued as rs1377087819; called by muse, mutect2, varscan2
- ST8SIA4 | c.102G>A p.T34= | Silent (SNP) | VAF 52/304 reads (17%) | catalogued as rs917045467, COSV51509639; called by muse, mutect2, varscan2
- STAG2 | c.985T>C p.L329= | Silent (SNP) | VAF 15/79 reads (19%) | called by muse, mutect2, varscan2
- TBC1D2 | c.753G>A p.Q251= | Silent (SNP) | VAF 35/115 reads (30%) | catalogued as rs1385161708; called by muse, mutect2, varscan2
- THBS1 | c.1428C>T p.G476= | Silent (SNP) | VAF 31/132 reads (23%) | catalogued as rs753944951; called by muse, mutect2, varscan2
- TMEM30A | c.960A>C p.G320= | Silent (SNP) | VAF 25/155 reads (16%) | catalogued as COSV57875216; called by muse, mutect2, varscan2
- ZNF516 | c.1368C>T p.Y456= | Silent (SNP) | VAF 42/205 reads (20%) | catalogued as rs1157146983; called by muse, mutect2, varscan2
- AC027559.1 | n.320C>T | RNA (SNP) | VAF 20/294 reads (7%) | catalogued as rs1472345869; called by muse, mutect2
- C2CD6 | c.1581+1156C>T | Intron (SNP) | VAF 15/59 reads (25%) | catalogued as rs577697309; called by muse, mutect2, varscan2
- DYRK2 | c.-32A>C | 5'UTR (SNP) | VAF 39/223 reads (17%) | called by muse, mutect2, varscan2
- EFHC1 | c.*273A>T | 3'UTR (SNP) | VAF 8/50 reads (16%) | catalogued as rs547492259; called by muse, mutect2, varscan2
- MSC | c.534+53C>T | Intron (SNP) | VAF 22/82 reads (27%) | catalogued as COSV100335952; called by muse, mutect2, varscan2
- PTTG1IP | c.*166C>T | 3'UTR (SNP) | VAF 48/205 reads (23%) | catalogued as rs756101716; called by muse, mutect2, varscan2
